Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5971, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5971-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) RIGHT NECK DISSECTION LEVEL 1A:
Two lymph nodes, no tumor present (0/2).
- (B) RIGHT NECK DISSECTION LEVEL 1B:
Three lymph nodes, no tumor present (0/3).
Salivary gland tissue, no tumor present.
- (C) RIGHT PARTIAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated
Tumor Features:
Gross: Ulcerating
Size: 2.5 cm in largest dimension
Invasion: Present, depth 1.3 cm
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural Invasion: Absent
Vascular Invasion: Absent
Lymphocyte Infiltration: Moderate
Mucosal Margin: Negative for invasive carcinoma, closest posterolateral margin (1.5 mm)
Deep Margin: Negative for invasive carcinoma
Dysplasia at Margin: Absent
- (D) RIGHT SELECTIVE NECK DISSECTION LEVEL 3:
Eight lymph nodes, no tumor present (0/8).
- (E) RIGHT SELECTIVE NECK DISSECTION LEVEL 4:
METASTATIC CARCINOMA IN 1 OF 8 LYMPH NODES (Level IV)
Positive Nodes = 1
Total Nodes = 8
Metastasis size = 1.3 cm
Extracapsular Extension: absent
- (F) RIGHT SELECTIVE NECK DISSECTION LEVEL 5:
Seven lymph nodes, no tumor present (0/7).
- (G) NEW RIGHT POSTERIOR LATERAL MARGIN:
Skeletal muscle and fibroconnective tissue, no tumor present.

GROSS DESCRIPTION

- (A) RIGHT NECK DISSECTION LEVEL 1A – Single fragment of fibrofatty tissue measuring 3.5 x 2.0 x 1.2 cm. Dissection reveals two possible lymph nodes ranging from 0.6 up to 0.9 cm in greatest dimension. Both possible lymph nodes and the rest of the soft tissue are entirely submitted in cassettes A1, one possible lymph node; A2, one bisected possibly lymph node; A3,4 and 5, the rest of the soft tissue.
- (B) RIGHT NECK DISSECTION LEVEL 1B – Received is a submandibular gland with attached scanty amount of fatty tissue. The gland measures 5.0 x 4.0 x 2.5 cm. Dissection reveals multiple possible lymph nodes ranging from 0.3 up to 1.0 cm in

[page 2 of 2]
[REDACTED]

their greatest dimension. Cut surface of the submandibular gland is unremarkable. Entire lymph nodes and representative sections of submandibular gland are submitted.

SECTION CODE: B1, three possible lymph nodes; B2, one possible lymph node; B3, one bisected possible lymph node; B4, one bisected possible lymph node; B5, representative sections of submandibular gland. [REDACTED]
(C) RIGHT PARTIAL GLOSSECTOMY – A partial glossectomy specimen (10.0 x 5.0 x 3.5 cm). The specimen is serially sectioned anterior to posterior.

A tan-pink, ill-defined tumor (2.5 x 2.0 x 1.3 cm) is identified and it is 1.0 to 2.0 mm from posterior lateral mucosal margin of resection. Representative sections are submitted.

SECTION CODE: C1, C2, Closest posterior lateral margin; C3-C5, anterior lateral margin; C6, medial margin; C7, posterior margin for frozen; C8-C10, deep margin; C10-C14, representative sections from the tumor submitted anterior to posterior. [REDACTED]

*FS/DX: POSTEROLATERAL MARGIN CLOSE (1-2 MM). REMAINDER OF MUCOSAL AND DEEP MARGINS NEGATIVE FOR TUMOR. [REDACTED]

(D) RIGHT SELECTIVE NECK DISSECTION LEVEL 3 – Received is a 4.0 x 2.5 x 1.5 cm portion of fibroadipose tissue. The specimen is dissected to reveal eight possible lymph nodes ranging from 0.2 up to 0.8 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: D1, two possible lymph nodes; D2, two possible lymph nodes. [REDACTED]
(E) RIGHT SELECTIVE NECK DISSECTION LEVEL 4 – Received is a 4.5 x 4.5 x 2.5 cm portion of fibroadipose tissue. The specimen is dissected to reveal eight possible lymph nodes ranging from 0.5 up to 2.8 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: E1, four possible lymph nodes; E2, three possible lymph nodes; E3-E6, one possible lymph node serially sectioned. [REDACTED]

(F) RIGHT SELECTIVE NECK DISSECTION LEVEL 5 – Received is a 2.8 x 2.8 x 1.0 cm portion of fibroadipose tissue. The specimen is dissected to reveal seven possible lymph nodes ranging from 0.1 up to 0.7 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: F1, four possible lymph nodes; F2, three possible lymph nodes. [REDACTED]
(G) NEW RIGHT POSTERIOR LATERAL MARGIN, STITCH ANTERIOR, INK MARKS LATERAL TRUE MARGIN – A piece of tan-brown soft tissue partially surfaced by mucosa (2.5 x 2.0 x 1.5 cm). One side of the specimen has ink, this area is shaved and submitted en face for frozen section in G. The remainder of the specimen is not submitted. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

CLINICAL HISTORY

Squamous cell carcinoma tongue (right) acquired tongue defect.

SNOMED CODES

[REDACTED]

Source: NCI Genomic Data Commons file 2bb991a4-b9f1-4b84-9538-3d085504237c (TCGA-CV-5971.B0FA95C1-9614-448A-976A-81D0779BE9D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).